Somatic mutation profile of tumor specimen TCGA-DJ-A3UP-01A (aliquot TCGA-DJ-A3UP-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.1 years (13,899 days).
Specimen TCGA-DJ-A3UP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd22035a-3894-4d85-b221-ed59db425641.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UP-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UP-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25b3b9fc-dfd1-4d4e-9b9a-3e1f36cac29b

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 99/256 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC005833.1 | c.1322A>T p.D441V | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious, low confidence (0); catalogued as COSV52896821; called by muse, mutect2
- SDC3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372651371; called by muse, mutect2, varscan2
- SLC49A3 | c.1607G>A p.G536D (on ENST00000404286 / NM_001294341.2; = p.G535D on NM_032219.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.988); catalogued as COSV59140097; called by muse, mutect2
- CTR9 | c.1873-5_1873-1del p.X625_splice | Splice Site (DEL) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- BAZ2B | c.3696C>T p.D1232= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV54275361; called by muse, mutect2, varscan2
- PRMT1 | c.18C>G p.A6= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs576649607, COSV55862940; called by muse, mutect2, varscan2
- VIPR2 | c.60C>T p.S20= | Silent (SNP) | VAF 9/154 reads (6%) | catalogued as COSV51105602, COSV51112007; called by muse, mutect2
